Somatic mutation profile of tumor specimen TCGA-CN-A6V3-01A (aliquot TCGA-CN-A6V3-01A-12D-A34J-08) from TCGA case TCGA-CN-A6V3, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 61.3 years (22,397 days).
Specimen TCGA-CN-A6V3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4f5c5ec7-fa7e-4868-a2e5-1c5048cc1127.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CN-A6V3-10A (Blood Derived Normal), aliquot TCGA-CN-A6V3-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5eb4a816-d637-4fdc-a252-355dff239f7f

The open-access MAF lists 259 somatic variants for this specimen: 187 protein-altering or splice-affecting, 64 silent, 8 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 158, Silent 64, Nonsense Mutation 17, Splice Site 6, Frame Shift Del 4, RNA 4, Intron 2, Splice Region 1, 5'Flank 1, In Frame Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.322G>T p.D108Y | Missense Mutation (SNP) | VAF 19/42 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913381, CM071585, CM973278, COSV58682998, COSV58690035, COSV58690777, COSV58726216; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CREBBP | c.4336C>T p.R1446C | Missense Mutation (SNP) | VAF 22/60 reads (37%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs398124146, COSV52113365, COSV52115600, COSV52116725; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- NSD1 | c.5129G>A p.C1710Y | Missense Mutation (SNP) | VAF 9/92 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM043035, COSV100728361, COSV100729547; called by muse, mutect2
- RHOA | c.109A>T p.T37S | Missense Mutation (SNP) | VAF 52/142 reads (37%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV101371071, COSV69043167; called by muse, mutect2, varscan2
- TP53 | c.314G>T p.G105V | Missense Mutation (SNP) | VAF 18/97 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs587781504, COSV52708806, COSV52766179, COSV52793434; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.3835C>A p.R1279S | Missense Mutation (SNP) | VAF 25/117 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.31); catalogued as COSV99711994; called by muse, mutect2, varscan2
- ABCC9 | c.3188C>G p.T1063R | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV99684270; called by muse, mutect2, varscan2
- ABL1 | c.589G>T p.E197* | Nonsense Mutation (SNP) | VAF 43/109 reads (39%) | catalogued as COSV100583370; called by muse, mutect2, varscan2
- AC004922.1 | c.1550G>T p.W517L | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99402796; called by muse, mutect2, varscan2
- ACVR1C | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV99694300; called by muse, mutect2, varscan2
- ADAM7 | c.568T>A p.S190T | Missense Mutation (SNP) | VAF 40/163 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0.014); catalogued as COSV99442883; called by muse, mutect2, varscan2
- ADCY9 | c.1942G>A p.G648R | Missense Mutation (SNP) | VAF 38/161 reads (24%) | SIFT tolerated (0.19); PolyPhen benign (0.383); catalogued as COSV53574271; called by muse, mutect2, varscan2
- ADGRG1 | c.1897G>T p.G633C | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101113318; called by muse, mutect2, varscan2
- ADGRG1 | c.1898G>T p.G633V | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101113320; called by muse, mutect2, varscan2
- ADGRL3 | c.3398A>T p.Y1133F (on ENST00000506720 / NM_001322402.2; = p.Y1065F on NM_015236.6) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.34); PolyPhen benign (0.193); catalogued as COSV101546823; called by muse, mutect2, varscan2
- AHNAK2 | c.11636A>G p.E3879G | Missense Mutation (SNP) | VAF 95/375 reads (25%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs201789836, COSV100315268; called by muse, mutect2, varscan2
- ANKRD30A | c.1708-2A>C p.X570_splice (on ENST00000611781; = p.X514_splice on NM_052997.2) | Splice Site (SNP) | VAF 14/282 reads (5%) | catalogued as COSV100652810; called by muse, mutect2
- ANLN | c.1087A>G p.T363A | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1338611365, COSV99731777; called by muse, mutect2, varscan2
- ARHGAP27 | c.1514G>T p.R505L (on ENST00000428638 / NM_001282290.1; = p.R164L on NM_199282.3) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV100976440; called by muse, mutect2, varscan2
- ARHGEF9 | c.1211T>C p.L404P | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV99491314; called by muse, mutect2, varscan2
- ATP13A3 | c.77G>C p.R26P | Missense Mutation (SNP) | VAF 20/168 reads (12%) | SIFT tolerated (0.35); PolyPhen benign (0.043); catalogued as COSV99756079; called by muse, mutect2, varscan2
- B4GALT1 | c.1194C>G p.S398R | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.085); catalogued as COSV101122944; called by muse, mutect2
- C12orf56 | c.1276G>T p.E426* (on ENST00000543942 / NM_001170633.2; = p.E266* on NM_001099676.3) | Nonsense Mutation (SNP) | VAF 12/34 reads (35%) | catalogued as COSV100398970; called by muse, mutect2, varscan2
- C2CD3 | c.4421A>T p.E1474V | Missense Mutation (SNP) | VAF 45/154 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.297); catalogued as COSV100486187; called by muse, mutect2, varscan2
- CABIN1 | c.5914G>T p.A1972S | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated, low confidence (0.83); PolyPhen benign (0.025); catalogued as COSV99572621; called by muse, mutect2, varscan2
- CC2D1A | c.494G>C p.R165P | Missense Mutation (SNP) | VAF 20/72 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100528201, COSV58785245; called by muse, mutect2, varscan2
- CCR3 | c.427C>T p.R143* | Nonsense Mutation (SNP) | VAF 15/81 reads (19%) | catalogued as rs754911047, COSV62462585; called by muse, mutect2, varscan2
- CD163L1 | c.2522C>A p.A841D | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV100549601, COSV58020248; called by muse, mutect2
- CD86 | c.642G>A p.M214I (on ENST00000330540 / NM_175862.5; = p.M208I on NM_006889.4) | Missense Mutation (SNP) | VAF 25/628 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.023); catalogued as COSV52605187, COSV52610547; called by muse, mutect2
- CDC20B | c.1015C>G p.H339D | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.796); catalogued as COSV99696449; called by muse, mutect2
- CDH5 | c.1917C>A p.H639Q | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV100438975, COSV58516898; called by muse, mutect2, varscan2
- CDK17 | c.997+2T>G p.X333_splice | Splice Site (SNP) | VAF 28/128 reads (22%) | catalogued as COSV99702419; called by muse, mutect2, varscan2
- CEP97 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 54/130 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100511511; called by muse, mutect2, varscan2
- CFAP53 | c.1066C>T p.Q356* | Nonsense Mutation (SNP) | VAF 46/200 reads (23%) | catalogued as rs868197962, COSV101274938; called by muse, mutect2, varscan2
- CHIA | c.1245C>A p.S415R (on ENST00000343320; = p.S307R on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/67 reads (33%) | SIFT tolerated (0.35); PolyPhen benign (0.348); catalogued as COSV58473662; called by muse, mutect2, varscan2
- CHRNE | c.425C>A p.A142D | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99544496; called by muse, mutect2, varscan2
- CLEC14A | c.1328T>C p.L443P | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.206); catalogued as COSV100643477; called by muse, mutect2, varscan2
- CNGA2 | c.1270G>A p.D424N | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.996); catalogued as COSV100323356; called by muse, mutect2, varscan2
- COL19A1 | c.3125A>T p.K1042M | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV100505018; called by muse, mutect2, varscan2
- COL5A1 | c.5215C>A p.H1739N | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV65671359; called by muse, mutect2, varscan2
- CPA5 | c.208T>C p.W70R | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782504813, COSV100812226; called by muse, mutect2, varscan2
- CTSF | c.1086C>G p.H362Q | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as COSV100074070; called by muse, mutect2, varscan2
- CUX2 | c.815G>C p.S272T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.13); catalogued as COSV99918486; called by muse, mutect2, varscan2
- CXCL9 | c.64+1G>A p.X22_splice | Splice Site (SNP) | VAF 52/218 reads (24%) | catalogued as COSV99345634; called by muse, mutect2, varscan2
- DBH | c.1714C>G p.R572G | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.345); catalogued as COSV101256815; called by muse, mutect2, varscan2
- DEF6 | c.1382+2T>A p.X461_splice | Splice Site (SNP) | VAF 13/65 reads (20%) | catalogued as COSV100359117; called by muse, mutect2, varscan2
- DHX35 | c.844A>G p.T282A | Missense Mutation (SNP) | VAF 35/151 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as COSV99326352; called by muse, mutect2, varscan2
- DMD | c.858T>A p.Y286* | Nonsense Mutation (SNP) | VAF 9/17 reads (53%) | catalogued as COSV99919033; called by muse, mutect2, varscan2
- DNAH5 | c.12713C>A p.S4238Y | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99444384; called by muse, mutect2, varscan2
- DOCK2 | c.5087G>T p.R1696L | Missense Mutation (SNP) | VAF 41/99 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56977328; called by muse, mutect2, varscan2
- DST | c.4339A>C p.K1447Q (on ENST00000361203 / NM_001374722.1; = p.K1121Q on NM_015548.5) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.075); catalogued as COSV99750477; called by muse, varscan2
- EFTUD2 | c.37A>G p.I13V | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.078); catalogued as COSV101274509; called by muse, mutect2, varscan2
- ERC2 | c.2211G>C p.E737D | Missense Mutation (SNP) | VAF 19/183 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV99880479; called by muse, mutect2, varscan2
- FAM47C | c.1352G>T p.R451L | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT tolerated, low confidence (0.45); PolyPhen possibly damaging (0.478); catalogued as rs782327673, COSV100792254, COSV63724552, COSV63728416; called by muse, mutect2, varscan2
- FMN2 | c.4255G>C p.G1419R | Missense Mutation (SNP) | VAF 23/98 reads (23%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.841); catalogued as COSV100142310, COSV60437245; called by muse, mutect2, varscan2
- FMOD | c.190A>T p.T64S | Missense Mutation (SNP) | VAF 15/69 reads (22%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV100724478; called by muse, mutect2, varscan2
- FN3KRP | c.725C>T p.S242L | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.613); catalogued as rs771035632, COSV53929195; called by muse, mutect2, varscan2
- FRAS1 | c.7418A>T p.D2473V | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99347835; called by muse, mutect2, varscan2
- GALNT12 | c.1316C>T p.P439L | Missense Mutation (SNP) | VAF 27/248 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as COSV100899027; called by muse, mutect2, varscan2
- GIPC2 | c.370G>T p.E124* | Nonsense Mutation (SNP) | VAF 8/88 reads (9%) | catalogued as COSV100883186; called by muse, mutect2
- GOLGA8G | c.1054C>A p.Q352K | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as rs750985763; called by mutect2, varscan2
- GRIK2 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV100022571, COSV100027790; called by muse, mutect2, varscan2
- GRM1 | c.2928G>T p.M976I | Missense Mutation (SNP) | VAF 50/193 reads (26%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.007); catalogued as COSV99263729; called by muse, mutect2, varscan2
- GRM2 | c.724G>T p.G242C | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV99622385; called by muse, mutect2, varscan2
- GRXCR1 | c.16A>T p.M6L | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101295605; called by muse, mutect2, varscan2
- HMCN1 | c.7218G>C p.L2406F | Missense Mutation (SNP) | VAF 19/117 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54891866, COSV99623515, COSV99624932; called by muse, mutect2
- IFI16 | c.1018A>T p.R340* | Nonsense Mutation (SNP) | VAF 14/88 reads (16%) | catalogued as COSV99856931; called by muse, mutect2, varscan2
- IGKV1D-43 | c.166G>A p.A56T | Missense Mutation (SNP) | VAF 80/284 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.051); catalogued as rs537963967; called by muse, mutect2, varscan2
- IGKV3-15 | c.275C>G p.T92S | Missense Mutation (SNP) | VAF 33/318 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.174); catalogued as rs537793232; called by muse, mutect2
- IMPG1 | c.145G>T p.E49* | Nonsense Mutation (SNP) | VAF 34/168 reads (20%) | catalogued as COSV64058640; called by muse, mutect2, varscan2
- KCND2 | c.755C>A p.P252H | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100473232; called by muse, mutect2, varscan2
- KIF21A | c.4024A>G p.I1342V (on ENST00000361418 / NM_001378440.1; = p.I1329V on NM_017641.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs767162841, COSV100735253; called by muse, mutect2, varscan2
- KLHL1 | c.514C>G p.H172D | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT tolerated (0.62); PolyPhen benign (0.006); catalogued as COSV100916928; called by muse, mutect2, varscan2
- LIG3 | c.1551T>G p.H517Q | Missense Mutation (SNP) | VAF 17/81 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99252084; called by muse, mutect2, varscan2
- LIPG | c.367T>A p.W123R | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99724247; called by muse, mutect2, varscan2
- LRFN5 | c.1958C>A p.T653K | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated, low confidence (0.77); PolyPhen benign (0.003); catalogued as COSV99982375; called by muse, mutect2, varscan2
- LRRC7 | c.704G>T p.G235V (on ENST00000651989 / NM_001370785.2; = p.G202V on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.486); catalogued as COSV99224199; called by muse, mutect2, varscan2
- LRRTM4 | c.1241A>T p.E414V | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.05); catalogued as COSV101297411; called by muse, mutect2
- MGAM | c.2108C>T p.S703F | Missense Mutation (SNP) | VAF 50/211 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); catalogued as COSV72075019; called by muse, mutect2, varscan2
- MORC1 | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 13/110 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.017); catalogued as COSV51728768, COSV99224933; called by muse, mutect2, varscan2
- MSH2 | c.485G>T p.G162V | Missense Mutation (SNP) | VAF 83/365 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as HM060002, COSV99253079; called by muse, mutect2, varscan2
- MYF6 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.68); PolyPhen benign (0.022); catalogued as COSV99952636; called by muse, varscan2
- MYO3A | c.1534G>T p.E512* | Nonsense Mutation (SNP) | VAF 17/72 reads (24%) | catalogued as COSV56318987, COSV99778053; called by muse, mutect2, varscan2
- NALCN | c.1674C>G p.D558E | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.67); PolyPhen benign (0.141); catalogued as COSV51944674, COSV99212786; called by muse, mutect2, varscan2
- NAV2 | c.3560G>T p.G1187V (on ENST00000396087 / NM_001244963.2; = p.G1164V on NM_145117.5) | Missense Mutation (SNP) | VAF 15/85 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.05); catalogued as COSV100215987; called by muse, mutect2, varscan2
- NAV3 | c.1565C>G p.P522R | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as COSV57065714, COSV99886565; called by muse, mutect2, varscan2
- NLRP2 | c.1988C>T p.P663L | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0.005); catalogued as rs775271805, COSV99671830; called by muse, mutect2, varscan2
- NME8 | c.22G>T p.V8F | Missense Mutation (SNP) | VAF 36/181 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.258); catalogued as COSV99552723; called by muse, mutect2, varscan2
- NPAP1 | c.1184C>A p.T395N | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.455); catalogued as COSV100274699; called by muse, mutect2, varscan2
- NPFFR2 | c.1203C>G p.Y401* | Nonsense Mutation (SNP) | VAF 21/117 reads (18%) | catalogued as rs538543232, COSV100440247, COSV58146856, COSV58152388; called by muse, mutect2, varscan2
- NRG3 | c.1303C>A p.H435N | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.006); catalogued as COSV100930528; called by muse, mutect2, varscan2
- NSD1 | c.5307G>T p.W1769C | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100728362; called by muse, mutect2, varscan2
- OGN | c.82C>A p.R28S | Missense Mutation (SNP) | VAF 42/96 reads (44%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV52760226, COSV52760887; called by muse, mutect2, varscan2
- OR14C36 | c.830C>A p.S277Y | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.248); catalogued as COSV58603100; called by muse, mutect2, varscan2
- OR1J4 | c.807C>G p.D269E | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.033); catalogued as COSV100534230; called by muse, mutect2, varscan2
- OR2M2 | c.862C>G p.L288V | Missense Mutation (SNP) | VAF 61/260 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV100677150, COSV100677156; called by muse, varscan2
- OR2M2 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 53/294 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.03); catalogued as rs758856171, COSV62897962; called by muse, varscan2
- OR2M7 | c.853C>A p.L285M | Missense Mutation (SNP) | VAF 32/112 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as COSV100522404; called by muse, mutect2, varscan2
- OR2T3 | c.296C>G p.P99R | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.29); PolyPhen benign (0.219); catalogued as rs759032581, COSV100613033, COSV62081664; called by muse, mutect2, varscan2
- OR2T8 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as rs778091297, COSV100178017; called by muse, mutect2
- OR5B12 | c.743T>A p.I248N | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV100222319; called by muse, mutect2, varscan2
- OR5D13 | c.451T>A p.Y151N | Missense Mutation (SNP) | VAF 57/245 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100686665, COSV100686703, COSV100686765; called by muse, mutect2, varscan2
- OR5D16 | c.544G>A p.E182K | Missense Mutation (SNP) | VAF 22/90 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV101003826; called by muse, mutect2, varscan2
- OR5I1 | c.355G>C p.A119P | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.791); catalogued as COSV100041191, COSV56885436; called by muse, mutect2, varscan2
- OR6T1 | c.152T>A p.I51K | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.028); catalogued as COSV100189695; called by muse, mutect2, varscan2
- PCDH11X | c.67G>A p.A23T | Missense Mutation (SNP) | VAF 44/78 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV100007573; called by muse, varscan2
- PCDH11X | c.147G>T p.L49F | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.995); catalogued as COSV100007710; called by muse, varscan2
- PCDH9 | c.2185G>C p.D729H | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100118045, COSV60537925; called by muse, mutect2, varscan2
- PDCD11 | c.3194C>T p.A1065V | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.69); PolyPhen benign (0.014); catalogued as COSV100874228; called by muse, mutect2, varscan2
- PDHA2 | c.468G>T p.K156N | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV99756414; called by muse, mutect2, varscan2
- PDK4 | c.683C>A p.T228K | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99138713; called by muse, mutect2, varscan2
- PGBD2 | c.617A>T p.D206V | Missense Mutation (SNP) | VAF 43/187 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100251839; called by muse, mutect2, varscan2
- PKD2L1 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 23/129 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs1295022780, COSV100559275; called by muse, mutect2, varscan2
- PKHD1L1 | c.3882C>G p.C1294W | Missense Mutation (SNP) | VAF 22/251 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV101005224; called by muse, mutect2
- PKP4 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 4/29 reads (14%) | SIFT tolerated (0.43); PolyPhen benign (0.182); catalogued as COSV101080130; called by muse, mutect2
- PLCB4 | c.2303C>A p.A768D | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99594119; called by muse, mutect2, varscan2
- PLPPR5 | c.330C>G p.C110W | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54179474, COSV99586907; called by muse, mutect2
- PMFBP1 | c.1148A>G p.Q383R | Missense Mutation (SNP) | VAF 49/171 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.057); catalogued as COSV99400051; called by muse, mutect2, varscan2
- POLR3E | c.432G>T p.K144N | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100241876; called by muse, varscan2
- PPFIA2 | c.1760G>C p.R587T | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.943); catalogued as COSV100331477; called by muse, mutect2, varscan2
- PPP1R9A | c.348G>T p.L116F | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV99194550; called by muse, mutect2, varscan2
- PPP2R2D | c.1090A>T p.M364L | Missense Mutation (SNP) | VAF 15/73 reads (21%) | SIFT tolerated (0.33); PolyPhen benign (0.014); catalogued as COSV101409018; called by muse, mutect2, varscan2
- PRAMEF2 | c.1000C>T p.R334C | Missense Mutation (SNP) | VAF 100/437 reads (23%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as rs765474771, COSV53573647; called by muse, varscan2
- PRDM9 | c.982C>T p.Q328* | Nonsense Mutation (SNP) | VAF 26/160 reads (16%) | catalogued as COSV99689701; called by muse, mutect2, varscan2
- PTPRC | c.2156C>G p.P719R | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100722070; called by muse, mutect2, varscan2
- RAP1GAP | c.314T>C p.L105P | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.437); catalogued as COSV99264672; called by muse, mutect2, varscan2
- RESF1 | c.530C>T p.P177L | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as rs1428915741, COSV57023193; called by muse, mutect2, varscan2
- RIMS2 | c.2602T>C p.Y868H (on ENST00000666250 / NM_001348490.2; = p.Y676H on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99156743; called by muse, mutect2, varscan2
- RP1 | c.4773G>C p.W1591C | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.062); catalogued as COSV55123166, COSV99606116; called by muse, mutect2, varscan2
- SEMA6D | c.1624G>T p.G542C | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.586); catalogued as COSV100316352; called by muse, mutect2, varscan2
- SLC30A10 | c.706C>G p.L236V | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100751399; called by muse, mutect2, varscan2
- SLC8A2 | c.2113G>A p.D705N | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.242); catalogued as COSV99369596; called by muse, varscan2
- SLIT2 | c.1507G>T p.D503Y | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs763158714, COSV56568329, COSV56572530; called by muse, mutect2
- SLITRK3 | c.1019G>A p.R340Q | Missense Mutation (SNP) | VAF 202/431 reads (47%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.968); catalogued as rs749713620, COSV53846718, COSV53850770; called by muse, mutect2, varscan2
- SMURF2 | c.433G>T p.G145* | Nonsense Mutation (SNP) | VAF 35/159 reads (22%) | catalogued as COSV99300264; called by muse, mutect2, varscan2
- SNRPC | c.467G>T p.R156L | Missense Mutation (SNP) | VAF 26/81 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.931); catalogued as COSV55075703, COSV99765140; called by muse, mutect2, varscan2
- SORBS2 | c.611A>T p.K204I (on ENST00000284776 / NM_021069.5; = p.K250I on NM_003603.6) | Missense Mutation (SNP) | VAF 45/177 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV99509369; called by muse, mutect2, varscan2
- SPATA7 | c.427T>C p.F143L | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.453); catalogued as COSV99247679; called by muse, mutect2, varscan2
- SPEG | c.726C>G p.S242R | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.554); catalogued as COSV100403130; called by muse, mutect2
- SRCAP | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99349124; called by muse, mutect2, varscan2
- SRCAP | c.6883A>T p.M2295L | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as COSV99349131; called by muse, mutect2, varscan2
- SRPK2 | c.1910A>C p.K637T | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99995708; called by muse, mutect2, varscan2
- STAB1 | c.6823T>A p.C2275S | Missense Mutation (SNP) | VAF 35/103 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100194476; called by muse, mutect2, varscan2
- STARD13 | c.835G>T p.G279W (on ENST00000336934 / NM_001243476.3; = p.G161W on NM_052851.3) | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.566); catalogued as COSV99715403; called by muse, mutect2, varscan2
- SULF2 | c.2164A>G p.M722V | Missense Mutation (SNP) | VAF 86/228 reads (38%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.942); catalogued as COSV100736948; called by muse, mutect2, varscan2
- SYNE1 | c.13742C>A p.A4581E (on ENST00000367255 / NM_182961.4; = p.A4510E on NM_033071.3) | Missense Mutation (SNP) | VAF 42/160 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV99551649; called by muse, mutect2, varscan2
- TAF1L | c.5164G>T p.G1722W | Missense Mutation (SNP) | VAF 39/323 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.624); catalogued as rs903517850, COSV99644031; called by muse, mutect2, varscan2
- TAPT1 | c.757G>A p.A253T | Missense Mutation (SNP) | VAF 8/69 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.191); catalogued as COSV100460942; called by muse, mutect2, varscan2
- TARBP1 | c.2929A>G p.I977V | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.91); PolyPhen benign (0.031); catalogued as rs766084833, COSV99241009; called by muse, mutect2, varscan2
- TBC1D4 | c.1238A>T p.Y413F | Missense Mutation (SNP) | VAF 12/57 reads (21%) | SIFT tolerated (1); PolyPhen possibly damaging (0.801); catalogued as rs752203792, COSV100884512; called by muse, mutect2, varscan2
- TCHH | c.4865G>T p.R1622L | Missense Mutation (SNP) | VAF 31/166 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.349); catalogued as COSV100914884, COSV64275588; called by muse, mutect2, varscan2
- TENM3 | c.6761C>A p.T2254N | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as COSV101304803; called by muse, mutect2, varscan2
- TFCP2 | c.76C>A p.L26M | Missense Mutation (SNP) | VAF 42/166 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99227439; called by muse, mutect2, varscan2
- TINAGL1 | c.514G>T p.E172* | Nonsense Mutation (SNP) | VAF 10/37 reads (27%) | catalogued as COSV99592633; called by muse, mutect2, varscan2
- TJP1 | c.620T>C p.F207S | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100632227; called by muse, mutect2, varscan2
- TNKS1BP1 | c.332G>T p.G111V | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.448); catalogued as COSV100835771; called by muse, mutect2, varscan2
- TNKS1BP1 | c.331G>T p.G111* | Nonsense Mutation (SNP) | VAF 7/39 reads (18%) | catalogued as COSV100835772; called by muse, mutect2, varscan2
- TOR1AIP1 | c.161G>A p.R54Q | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs1344989599, COSV99620932; called by muse, mutect2, varscan2
- TRAF3 | c.245G>T p.S82I | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as rs1235290905, COSV100693414; called by muse, mutect2, varscan2
- TRHR | c.273G>T p.W91C | Missense Mutation (SNP) | VAF 54/369 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61232921, COSV61235137; called by muse, mutect2, varscan2
- TRIM62 | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT tolerated (0.86); PolyPhen possibly damaging (0.559); catalogued as rs371211863; called by muse, mutect2, varscan2
- TTPA | c.370C>A p.P124T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); catalogued as COSV52647854, COSV99478384; called by muse, mutect2, varscan2
- URB2 | c.3973G>T p.V1325F | Missense Mutation (SNP) | VAF 25/110 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); catalogued as COSV99270574; called by muse, mutect2, varscan2
- UTRN | c.1081G>C p.A361P | Missense Mutation (SNP) | VAF 19/98 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100839482; called by muse, mutect2, varscan2
- VDR | c.1275G>T p.E425D | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.109); catalogued as COSV99968516; called by muse, mutect2, varscan2
- WASHC4 | c.2495C>T p.T832M | Missense Mutation (SNP) | VAF 21/179 reads (12%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.917); catalogued as rs765821676, COSV100161991; called by muse, mutect2, varscan2
- WDR31 | c.780G>T p.T260= (on ENST00000374193 / NM_001006615.3; = p.T259= on NM_145241.5) | Splice Region (SNP) | VAF 23/145 reads (16%) | catalogued as COSV100516581, COSV59145447; called by muse, mutect2, varscan2
- XPNPEP3 | c.964A>G p.I322V | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.46); PolyPhen benign (0.217); catalogued as COSV100846612; called by muse, mutect2, varscan2
- ZDHHC12 | c.482G>A p.W161* | Nonsense Mutation (SNP) | VAF 34/226 reads (15%) | catalogued as COSV99403233; called by muse, mutect2, varscan2
- ZNF138 | c.897A>G p.I299M (on ENST00000307355 / NM_001367572.1; = p.I273M on NM_006524.4) | Missense Mutation (SNP) | VAF 17/64 reads (27%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.659); catalogued as COSV100245577; called by muse, mutect2, varscan2
- ZNF37A | c.200G>A p.W67* | Nonsense Mutation (SNP) | VAF 11/57 reads (19%) | catalogued as COSV100697248; called by muse, mutect2, varscan2
- ZNF479 | c.635C>A p.S212Y | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as COSV100482333, COSV100482422; called by muse, mutect2, varscan2
- ZNF479 | c.386G>T p.C129F | Missense Mutation (SNP) | VAF 41/182 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as COSV58637238, COSV58641252; called by muse, mutect2, varscan2
- ZNF550 | c.691T>C p.Y231H | Missense Mutation (SNP) | VAF 31/139 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV100286352; called by muse, mutect2, varscan2
- ZNF804B | c.1415C>G p.S472C | Missense Mutation (SNP) | VAF 14/97 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100301540; called by muse, mutect2, varscan2
- ZNF85 | c.502C>A p.H168N | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.596); catalogued as COSV100059422, COSV60215017; called by muse, mutect2
- AL645922.1 | c.123G>T p.W41C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.956); called by muse, mutect2
- ANKRD30A | c.2422-2A>C p.X808_splice (on ENST00000611781; = p.X752_splice on NM_052997.2) | Splice Site (SNP) | VAF 6/33 reads (18%) | called by mutect2, varscan2
- CTSO | c.917del p.G306Efs*36 | Frame Shift Del (DEL) | VAF 19/120 reads (16%) | called by mutect2, pindel, varscan2
- DDX3X | c.345del p.F115Lfs*105 (on ENST00000399959; = p.F116Lfs*105 on NM_001356.5) | Frame Shift Del (DEL) | VAF 23/67 reads (34%) | called by mutect2, pindel, varscan2
- DSTN | c.36_55del p.C12* | Nonsense Mutation (DEL) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- GRK1 | c.352del p.Q118Rfs*13 | Frame Shift Del (DEL) | VAF 15/59 reads (25%) | called by mutect2, pindel, varscan2
- KCNH1 | c.709del p.Y237Ifs*44 | Frame Shift Del (DEL) | VAF 18/85 reads (21%) | called by mutect2, pindel, varscan2
- KDR | c.1255+2_1255+3del p.X419_splice | Splice Site (DEL) | VAF 17/92 reads (18%) | called by mutect2, pindel, varscan2
- KIRREL2 | c.972_980del p.D324_G326del | In Frame Del (DEL) | VAF 11/48 reads (23%) | called by mutect2, pindel, varscan2
- NBEA | c.6034G>A p.A2012T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.376); called by muse, mutect2
- ZNF658 | c.867A>T p.K289N | Missense Mutation (SNP) | VAF 92/539 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- AC004593.2 | c.834A>G p.T278= | Silent (SNP) | VAF 10/70 reads (14%) | catalogued as COSV99764383; called by muse, mutect2, varscan2
- ACSM2B | c.549G>A p.V183= | Silent (SNP) | VAF 38/379 reads (10%) | catalogued as COSV100312271, COSV100312682; called by muse, mutect2
- ADGRB3 | c.1926C>A p.V642= | Silent (SNP) | VAF 18/79 reads (23%) | catalogued as COSV100999625; called by muse, mutect2, varscan2
- ADGRL2 | c.2025C>A p.L675= (on ENST00000370717 / NM_001366005.1; = p.L662= on NM_012302.4) | Silent (SNP) | VAF 20/168 reads (12%) | catalogued as COSV99586909; called by muse, mutect2, varscan2
- ATP13A3 | c.1320G>A p.G440= | Silent (SNP) | VAF 20/122 reads (16%) | catalogued as COSV99756075; called by muse, mutect2, varscan2
- CACNA1F | c.4662C>A p.I1554= | Silent (SNP) | VAF 15/99 reads (15%) | catalogued as COSV100544316; called by muse, mutect2, varscan2
- CCIN | c.1089C>T p.I363= | Silent (SNP) | VAF 45/202 reads (22%) | catalogued as rs147398180; called by muse, mutect2, varscan2
- CD163L1 | c.1038C>T p.T346= | Silent (SNP) | VAF 25/96 reads (26%) | catalogued as rs1410595361, COSV58011511; called by muse, mutect2, varscan2
- COL11A1 | c.5229C>T p.S1743= | Silent (SNP) | VAF 11/90 reads (12%) | catalogued as COSV100617223, COSV62199448; called by muse, mutect2, varscan2
- CTAG2 | c.624T>A p.P208= | Silent (SNP) | VAF 30/65 reads (46%) | catalogued as COSV99908751; called by muse, mutect2, varscan2
- DCHS1 | c.5400A>G p.L1800= | Silent (SNP) | VAF 14/51 reads (27%) | catalogued as COSV100201402; called by muse, mutect2, varscan2
- DDC | c.168C>T p.I56= | Silent (SNP) | VAF 34/155 reads (22%) | catalogued as COSV100779098; called by muse, mutect2, varscan2
- FAM135B | c.4137C>A p.G1379= | Silent (SNP) | VAF 82/446 reads (18%) | catalogued as COSV99418237; called by muse, mutect2, varscan2
- GABRB3 | c.1065G>A p.K355= | Silent (SNP) | VAF 43/194 reads (22%) | catalogued as COSV100157963, COSV54674152; called by muse, mutect2, varscan2
- HS3ST4 | c.918C>T p.P306= | Silent (SNP) | VAF 55/214 reads (26%) | catalogued as rs557934955, COSV100499933, COSV58807445; called by muse, mutect2, varscan2
- KCNA4 | c.492C>T p.G164= | Silent (SNP) | VAF 9/118 reads (8%) | catalogued as rs1342472405, COSV100068461; called by muse, mutect2
- KMT2A | c.603A>G p.K201= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV100627840; called by muse, mutect2, varscan2
- LILRB5 | c.1071G>A p.K357= | Silent (SNP) | VAF 13/74 reads (18%) | catalogued as COSV60254189; called by muse, mutect2, varscan2
- LRRK1 | c.582G>A p.V194= | Silent (SNP) | VAF 15/47 reads (32%) | catalogued as COSV99437294; called by muse, mutect2, varscan2
- LRRTM1 | c.618C>A p.A206= | Silent (SNP) | VAF 29/139 reads (21%) | catalogued as COSV99701672; called by muse, mutect2, varscan2
- MAP1B | c.6174C>A p.S2058= | Silent (SNP) | VAF 19/139 reads (14%) | catalogued as COSV57098313; called by muse, mutect2, varscan2
- MEGF10 | c.1215C>T p.Y405= | Silent (SNP) | VAF 77/174 reads (44%) | catalogued as rs781762135, COSV99174685; ClinVar: uncertain significance; called by muse, varscan2
- MRPL47 | c.426A>G p.L142= | Silent (SNP) | VAF 111/248 reads (45%) | catalogued as COSV99372830; called by muse, mutect2, varscan2
- MS4A14 | c.72T>A p.T24= | Silent (SNP) | VAF 18/66 reads (27%) | catalogued as COSV100279318; called by muse, mutect2, varscan2
- MTUS2 | c.495G>A p.K165= | Silent (SNP) | VAF 26/114 reads (23%) | catalogued as COSV70923503; called by muse, mutect2, varscan2
- MUC16 | c.7437C>A p.V2479= | Silent (SNP) | VAF 18/95 reads (19%) | catalogued as COSV101197856; called by muse, mutect2, varscan2
- NCOA3 | c.3639G>A p.Q1213= | Silent (SNP) | VAF 22/71 reads (31%) | catalogued as COSV59068748; called by muse, mutect2, varscan2
- NEK11 | c.1476G>A p.E492= | Silent (SNP) | VAF 18/345 reads (5%) | catalogued as rs145914506, COSV101272951; called by muse, mutect2
- NPAS4 | c.2136C>T p.D712= | Silent (SNP) | VAF 38/151 reads (25%) | catalogued as rs764724471, COSV100214746; called by muse, mutect2, varscan2
- OR10AD1 | c.129C>A p.G43= | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as COSV100046710; called by muse, mutect2, varscan2
- OR2A2 | c.186C>T p.L62= | Silent (SNP) | VAF 67/267 reads (25%) | catalogued as rs759170009, COSV101286612; called by muse, mutect2, varscan2
- OR51B4 | c.378A>G p.P126= | Silent (SNP) | VAF 21/103 reads (20%) | catalogued as COSV100970472; called by muse, mutect2, varscan2
- OR5T2 | c.276C>T p.S92= | Silent (SNP) | VAF 16/59 reads (27%) | catalogued as COSV100506791; called by muse, mutect2, varscan2
- PCDH15 | c.2115A>T p.I705= | Silent (SNP) | VAF 21/112 reads (19%) | catalogued as COSV100214444; called by muse, mutect2, varscan2
- PCDH17 | c.2022C>A p.S674= | Silent (SNP) | VAF 57/203 reads (28%) | catalogued as COSV100931397, COSV64973109; called by muse, mutect2, varscan2
- PDAP1 | c.438C>T p.I146= | Silent (SNP) | VAF 32/112 reads (29%) | catalogued as COSV99402797; called by muse, mutect2, varscan2
- PDE3A | c.1074C>A p.T358= | Silent (SNP) | VAF 21/107 reads (20%) | catalogued as rs1457139545, COSV100761597; called by muse, mutect2, varscan2
- PGM3 | c.1158G>A p.K386= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV99392148; called by muse, mutect2
- PLIN4 | c.2733C>T p.T911= (on ENST00000301286; = p.T926= on NM_001367868.2) | Silent (SNP) | VAF 15/167 reads (9%) | catalogued as rs199625614; called by muse, mutect2
- RALGPS1 | c.1077G>A p.A359= | Silent (SNP) | VAF 14/148 reads (9%) | catalogued as rs758824247, COSV99400683; called by muse, mutect2
- RHAG | c.921T>A p.S307= | Silent (SNP) | VAF 30/118 reads (25%) | catalogued as COSV100006261; called by muse, mutect2, varscan2
- RIF1 | c.4443A>G p.K1481= | Silent (SNP) | VAF 21/108 reads (19%) | catalogued as COSV99689980; called by muse, mutect2, varscan2
- RIT2 | c.381C>A p.P127= | Silent (SNP) | VAF 86/314 reads (27%) | catalogued as COSV99949488; called by muse, mutect2, varscan2
- RP9 | c.555C>T p.H185= | Silent (SNP) | VAF 22/132 reads (17%) | catalogued as rs1440795786, COSV99777904; called by muse, mutect2, varscan2
- SAMD15 | c.720T>A p.T240= | Silent (SNP) | VAF 31/97 reads (32%) | catalogued as COSV99374735; called by muse, mutect2, varscan2
- SESTD1 | c.936A>G p.L312= | Silent (SNP) | VAF 93/408 reads (23%) | catalogued as rs771815005, COSV100090143; called by muse, mutect2, varscan2
- SLC6A17 | c.333C>T p.I111= | Silent (SNP) | VAF 8/32 reads (25%) | catalogued as rs1183018376, COSV100521060; called by muse, mutect2, varscan2
- SLIT2 | c.4164C>T p.I1388= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as COSV99880455; called by muse, mutect2, varscan2
- SLITRK3 | c.2892G>T p.P964= | Silent (SNP) | VAF 141/307 reads (46%) | catalogued as COSV53850899, COSV99578396; called by muse, mutect2, varscan2
- STAG1 | c.495C>G p.T165= | Silent (SNP) | VAF 9/150 reads (6%) | catalogued as COSV99364267; called by muse, mutect2
- STARD4 | c.555G>A p.A185= | Silent (SNP) | VAF 63/155 reads (41%) | catalogued as rs764151473, COSV99685201; called by muse, mutect2, varscan2
- SUPT6H | c.1902C>T p.A634= | Silent (SNP) | VAF 22/69 reads (32%) | catalogued as rs755417462, COSV100112037; called by muse, mutect2, varscan2
- SV2B | c.1623C>G p.V541= | Silent (SNP) | VAF 52/200 reads (26%) | catalogued as COSV100370351; called by muse, mutect2, varscan2
- SYNE1 | c.18078G>A p.E6026= (on ENST00000367255 / NM_182961.4; = p.E5955= on NM_033071.3) | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as rs146027815, COSV99551643; called by muse, mutect2, varscan2
- SYTL4 | c.675A>G p.P225= | Silent (SNP) | VAF 23/53 reads (43%) | catalogued as COSV99342612; called by muse, mutect2, varscan2
- TBC1D2 | c.1596G>A p.L532= | Silent (SNP) | VAF 9/21 reads (43%) | catalogued as COSV100579656; called by muse, mutect2, varscan2
- TMEM19 | c.945G>T p.L315= | Silent (SNP) | VAF 101/397 reads (25%) | catalogued as COSV99876782; called by muse, mutect2, varscan2
- TP53 | c.315C>T p.G105= | Silent (SNP) | VAF 18/97 reads (19%) | catalogued as COSV53637914; called by muse, mutect2, varscan2
- TRIO | c.5064G>T p.R1688= | Silent (SNP) | VAF 24/45 reads (53%) | catalogued as COSV100709739; called by muse, mutect2, varscan2
- TTBK2 | c.2946G>T p.L982= | Silent (SNP) | VAF 41/162 reads (25%) | catalogued as COSV99141067; called by muse, mutect2, varscan2
- USP28 | c.1758G>A p.L586= | Silent (SNP) | VAF 11/131 reads (8%) | catalogued as COSV50166125; called by muse, mutect2
- VPS13A | c.7173A>T p.A2391= | Silent (SNP) | VAF 98/280 reads (35%) | catalogued as COSV100652053; called by muse, mutect2, varscan2
- ZNF423 | c.189T>C p.N63= (on ENST00000563137 / NM_001379286.1; = p.N55= on NM_015069.4) | Silent (SNP) | VAF 47/236 reads (20%) | catalogued as COSV99279523; called by muse, mutect2, varscan2
- ZNF835 | c.621G>T p.T207= | Silent (SNP) | VAF 4/22 reads (18%) | catalogued as COSV101606248, COSV73379201; called by mutect2, varscan2
- AGAP7P | n.696G>A | RNA (SNP) | VAF 18/246 reads (7%) | called by muse, varscan2
- AL353804.7 | chrX:73851197 G>A | 3'Flank (SNP) | VAF 60/115 reads (52%) | catalogued as rs771284047; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65504068 A>T | 5'Flank (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- ASIC2 | c.556-179549C>G | Intron (SNP) | VAF 5/28 reads (18%) | catalogued as COSV99859136; called by muse, mutect2, varscan2
- DCHS2 | n.7578T>A | RNA (SNP) | VAF 14/85 reads (16%) | catalogued as COSV100600982; called by muse, mutect2, varscan2
- HERC2P3 | n.434C>T | RNA (SNP) | VAF 6/34 reads (18%) | called by muse, mutect2, varscan2
- MORF4 | n.745G>T | RNA (SNP) | VAF 77/301 reads (26%) | called by muse, mutect2, varscan2
- PPP1R8 | c.117+1596A>T | Intron (SNP) | VAF 37/195 reads (19%) | catalogued as COSV99360817; called by muse, mutect2, varscan2
